Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7X0, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7X0-01A (Primary Tumor).

Gross:

Encapsulated tumor of the small pelvis with ovoid shape (weight 22 g, dimensions 50x40x30 mm). On cut, grey-pink coloured with soft consistency.

Micro:

Solidly and alveolarly shaped paraganglioma with strongly positive chromogranin staining.

Immunohistochemic staining for S100 protein is positive in paraganglioma cells, sustentacular cells may be present but do not react. No angio- and capsular invasion were found in the representative specimen. MIB-1 positive in 1-2 tumor cells.

The tumor is extra-adrenally localized, according the PASS score (2/20) benign.

Procurement date:

Confirmation date:

CCF ICD-O-3
Paraganglioma, extra adrenal MS 8693/1
path
Paraganglioma, benign 8693/0
Site: Pelvis MS 849.5
JW 10/10/13

Source: NCI Genomic Data Commons file 8ec21287-98d8-4cc4-be3a-6bc3ca92d478 (TCGA-S7-A7X0.DEC66F18-B1B7-4E36-AB51-D9501F20CFE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).